TARGET case TARGET-30-PASJZC — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Liver and intrahepatic bile ducts. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/717c4844-5ef9-553b-bb90-0d62d976f909

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C22.9; Tissue or organ of origin: Liver; Classification of tumor: primary; Age at diagnosis: 0.2 years (74 days); Year of diagnosis: 2009; Days to last follow up: 2,631 days (7.2 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4S; Mitosis karyorrhexis index: Low.
   Pathology details: Percent tumor nuclei: 55.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 367 days (1.0 years); Days to first event: 367 days (1.0 years); First event: Relapse.
- Days to follow up: 2,631 days (7.2 years); Year of follow up: 2016.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASJZC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PASJZC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2631
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.45
- Histology: Favorable
- MKI: Low
- ICDO: C22.0
- ICDO Description: Liver Hepatic, NOS
- Site of Relapse: Primary site
